Somatic mutation profile of tumor specimen TCGA-ZJ-AAXB-01A (aliquot TCGA-ZJ-AAXB-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 42.4 years (15,492 days).
Specimen TCGA-ZJ-AAXB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57b4a9a7-0d19-4139-8abf-c4c7500a7fc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXB-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXB-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d3e67be-cd80-4bed-9c1f-77d4eb443887

The open-access MAF lists 159 somatic variants for this specimen: 117 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 36, Nonsense Mutation 6, Frame Shift Del 6, Splice Site 4, Frame Shift Ins 3, RNA 2, In Frame Del 2, 3'UTR 1, 5'Flank 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTB | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as COSV59322171; called by muse, mutect2, varscan2
- ACTN1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV99518269; called by muse, mutect2, varscan2
- ADGRA3 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99293616; called by muse, mutect2, varscan2
- AFF4 | c.174C>A p.N58K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99535229; called by muse, mutect2, varscan2
- AGAP4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV101432686; called by muse, varscan2
- ALMS1 | c.4805G>A p.G1602E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV100043270; called by muse, mutect2
- AMHR2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs986686481, COSV99143426; called by muse, mutect2, varscan2
- ASB15 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV99306854; called by muse, mutect2, varscan2
- ASCL1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV57152556; called by muse, mutect2, varscan2
- ATG9B | c.2260G>C p.G754R | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.367); catalogued as COSV99871966; called by muse, mutect2, varscan2
- ATRN | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs760560964, COSV53531305; called by muse, mutect2, varscan2
- B3GAT1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs144109297; called by muse, mutect2, varscan2
- BYSL | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV99539940; called by muse, varscan2
- C2CD3 | c.2993G>C p.G998A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV100487147; called by muse, mutect2
- CD5L | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100941085, COSV63822939; called by muse, mutect2, varscan2
- CDK4 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99226087; called by muse, mutect2, varscan2
- CENPB | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.261); catalogued as COSV100713571; called by muse, mutect2, varscan2
- CFAP61 | c.3550C>G p.Q1184E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99846013; called by muse, mutect2, varscan2
- CLDN1 | c.389-2A>T p.X130_splice | Splice Site (SNP) | VAF 36/232 reads (16%) | catalogued as COSV99790709; called by muse, mutect2, varscan2
- CLRN1 | c.448C>T p.L150F (on ENST00000327047 / NM_174878.3; = p.L74F on NM_052995.2) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99902614; called by muse, varscan2
- COL25A1 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs773360444, COSV101211597; called by muse, mutect2, varscan2
- CSF2RB | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as rs1263779773, COSV99454248; called by muse, mutect2, varscan2
- CSRP3 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99788349; called by muse, mutect2, varscan2
- CST4 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54150460, COSV99463353; called by muse, mutect2, varscan2
- DBF4 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99719520; called by muse, mutect2, varscan2
- DCXR | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as COSV100178897; called by muse, mutect2, varscan2
- DGKK | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs782552872, COSV101053147; called by muse, mutect2, varscan2
- DNAH2 | c.2775A>T p.Q925H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101209513, COSV66724200; called by muse, mutect2, varscan2
- DOCK4 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768165193, COSV101455551; called by muse, mutect2, varscan2
- EHMT2 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); catalogued as COSV57667339, COSV99999155; called by muse, mutect2, varscan2
- FSIP2 | c.18095A>G p.K6032R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100555853; called by muse, mutect2, varscan2
- HECTD4 | c.8558A>T p.H2853L | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV101108161; called by muse, mutect2, varscan2
- IRGC | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV99746449; called by muse, mutect2, varscan2
- ITSN2 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV100743967, COSV61946504; called by muse, mutect2, varscan2
- KMT2D | c.11714A>T p.Q3905L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs1334139538, COSV56436687; called by muse, mutect2
- LAMC3 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs751314241, COSV63094440; called by muse, mutect2, varscan2
- LMAN1L | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as rs1156972037, COSV100547783; called by muse, mutect2, varscan2
- LMTK3 | c.2639C>A p.A880E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV99540973; called by muse, mutect2, varscan2
- LRP6 | c.2848G>A p.D950N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.649); catalogued as COSV99743499; called by muse, mutect2, varscan2
- MACF1 | c.11612A>T p.E3871V (on ENST00000372915; = p.E1804V on NM_012090.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99245963; called by muse, mutect2, varscan2
- MAGEB10 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.865); catalogued as COSV100775344; called by muse, mutect2, varscan2
- MAGI1 | c.608C>G p.T203R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV100442403; called by muse, mutect2, varscan2
- MAST2 | c.4851G>A p.W1617* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV53105084, COSV99422576; called by muse, mutect2, varscan2
- MCOLN3 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV100352900; called by muse, mutect2, varscan2
- METTL25 | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV50258688; called by muse, mutect2, varscan2
- MOCS3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54865881, COSV54867244; called by muse, mutect2, varscan2
- MYO5A | c.602C>G p.P201R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100697975; called by muse, mutect2, varscan2
- NFIC | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100545572, COSV59410241; called by muse, mutect2
- NOL4L | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100675669; called by muse, mutect2, varscan2
- NT5DC1 | c.1161A>T p.E387D | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.098); catalogued as COSV100127087; called by muse, mutect2
- OIT3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100468228; called by muse, mutect2, varscan2
- OR10K1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV99193824; called by muse, mutect2, varscan2
- PBDC1 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV100972852; called by muse, mutect2, varscan2
- PCDHB16 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99502546; called by mutect2, varscan2
- PCDHGA2 | c.1976C>T p.T659M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as rs759610387, COSV99543344; called by muse, mutect2, varscan2
- PDCD2L | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs146212339; called by muse, mutect2, varscan2
- PDZD2 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56850053; called by muse, mutect2, varscan2
- PKHD1 | c.9848T>C p.F3283S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100584057; called by muse, mutect2
- PLCB1 | c.1711G>C p.V571L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100571785; called by muse, mutect2
- PLEKHA5 | c.2891G>C p.R964T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs367969719; called by muse, mutect2, varscan2
- POLR1B | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs755620310, COSV99638198; called by muse, mutect2, varscan2
- POR | c.1549C>A p.R517S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100115699; called by muse, mutect2, varscan2
- PREX2 | c.4231+1G>A p.X1411_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as rs749498111, COSV55798304, COSV55803984; called by muse, mutect2, varscan2
- PTPN9 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100144481; called by muse, mutect2, varscan2
- QRSL1 | c.381-1G>C p.X127_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100945269; called by muse, mutect2, varscan2
- RASAL2 | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100862760; called by muse, mutect2, varscan2
- RIF1 | c.1410T>G p.F470L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99690967; called by muse, mutect2, varscan2
- RNF130 | c.766-2A>C p.X256_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99992881; called by muse, mutect2, varscan2
- RNF19A | c.2348C>A p.T783N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV100347968; called by muse, mutect2, varscan2
- SDC1 | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs962025606, COSV99587261; called by muse, mutect2, varscan2
- SEZ6 | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV57980572; called by muse, mutect2, varscan2
- SHKBP1 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV99399286; called by muse, mutect2, varscan2
- SLC16A7 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99676751; called by muse, mutect2, varscan2
- SLC9A7 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.871); catalogued as COSV100092548; called by muse, mutect2, varscan2
- SLITRK3 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579765; called by muse, mutect2, varscan2
- SMC1A | c.921C>G p.H307Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100447607; called by muse, mutect2, varscan2
- SPIN2B | c.768A>T p.K256N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52068991, COSV99328188; called by muse, mutect2, varscan2
- STXBP3 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV100894045; called by muse, mutect2, varscan2
- SYCP2 | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100698381; called by muse, mutect2, varscan2
- TDGF1 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56126763, COSV99947579; called by muse, mutect2, varscan2
- TDRD6 | c.2651T>C p.L884P | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778515332, COSV100288054; called by muse, mutect2, varscan2
- TEC | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs750190240, COSV67405584; called by muse, mutect2, varscan2
- TEPSIN | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs778828496, COSV56142656; called by muse, varscan2
- THADA | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV100369237; called by muse, mutect2, varscan2
- TIMP4 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs201048395, COSV99826022; called by muse, mutect2, varscan2
- TNFRSF11B | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs371566584, COSV99816854; called by muse, mutect2, varscan2
- TNRC6B | c.4501A>T p.T1501S (on ENST00000454349 / NM_001162501.2; = p.T1391S on NM_015088.3) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100110196; called by muse, mutect2, varscan2
- TPX2 | c.1108C>G p.P370A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55917308; called by muse, mutect2
- TSFM | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV100103728; called by muse, mutect2, varscan2
- VCAN | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs143128206, COSV54101467; called by muse, mutect2, varscan2
- VSIG4 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.536); catalogued as rs753786786, COSV101038243; called by mutect2, varscan2
- WNK3 | c.2209C>G p.R737G | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100671875, COSV63614270; called by muse, mutect2, varscan2
- YPEL3 | c.231C>G p.I77M (on ENST00000398838 / NM_001145524.2; = p.I115M on NM_031477.5) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99661736; called by muse, mutect2, varscan2
- ZBED9 | c.958C>A p.H320N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101509349; called by muse, mutect2, varscan2
- ZBTB7C | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100134542, COSV100134545; called by muse, mutect2, varscan2
- ZC3H7B | c.408C>G p.Y136* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100687613; called by muse, mutect2, varscan2
- ZDHHC17 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV100602207; called by muse, mutect2, varscan2
- ZFP41 | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.097); catalogued as COSV100414764; called by muse, mutect2, varscan2
- ZNF121 | c.651A>T p.K217N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.855); catalogued as COSV100248241; called by muse, mutect2, varscan2
- ZNF423 | c.1844C>T p.S615L (on ENST00000563137 / NM_001379286.1; = p.S607L on NM_015069.4) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs754474774, COSV52184613, COSV52199472; called by muse, mutect2, varscan2
- ZNF671 | c.1185G>C p.R395S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV100235200; called by muse, mutect2, varscan2
- ZNF681 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV101267538; called by muse, mutect2, varscan2
- ACAN | c.7344del p.F2448Lfs*9 (on ENST00000560601 / NM_001369268.1; = p.F2372Lfs*9 on NM_001135.3) | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- CLTCL1 | c.3605G>C p.G1202A | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- DSCAM | c.1433_1436del p.D478Gfs*21 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- GPCPD1 | c.462dup p.S155Ifs*2 | Frame Shift Ins (INS) | VAF 17/151 reads (11%) | called by mutect2, varscan2
- IGHG3 | c.196A>T p.S66C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LAMA5 | c.10925dup p.L3643Sfs*8 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- LRRC1 | c.626dup p.S210Vfs*20 | Frame Shift Ins (INS) | VAF 30/167 reads (18%) | called by mutect2, pindel, varscan2
- LRRC37A2 | c.3748_3750del p.P1250del | In Frame Del (DEL) | VAF 20/178 reads (11%) | called by mutect2, varscan2
- LTN1 | c.3475_3483del p.C1159_T1161del | In Frame Del (DEL) | VAF 38/126 reads (30%) | called by mutect2, pindel, varscan2
- LZTS3 | c.347_359del p.V116Efs*32 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- NCL | c.81_82del p.D27Efs*2 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.1584C>A p.C528* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- UBE3B | c.1812_1813del p.D605Lfs*19 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.9000del p.E3001Kfs*6 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- ACACB | c.4296C>T p.H1432= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100623134; called by muse, mutect2, varscan2
- ARHGEF2 | c.1116C>T p.P372= (on ENST00000361247 / NM_001162383.2; = p.P344= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs1000578033, COSV100560908; called by muse, mutect2, varscan2
- CABS1 | c.753C>A p.T251= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99909133; called by muse, mutect2, varscan2
- CDH20 | c.2382G>A p.S794= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs978379090, COSV53010393, COSV99406151; called by muse, mutect2, varscan2
- CENPB | c.1206G>A p.K402= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1283910968, COSV100713572, COSV60148605; called by muse, mutect2, varscan2
- CFAP43 | c.1626G>A p.S542= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs747748851, COSV99530594, COSV99531031; called by muse, mutect2, varscan2
- CHMP4B | c.291G>A p.E97= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV99459952; called by muse, mutect2, varscan2
- CTDSPL2 | c.795G>A p.P265= | Silent (SNP) | VAF 52/203 reads (26%) | catalogued as rs372317002; called by muse, mutect2, varscan2
- DNAH17 | c.1992C>T p.D664= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs1464624354, COSV101102604; called by muse, mutect2, varscan2
- DRD5 | c.555G>C p.A185= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100431960; called by muse, mutect2, varscan2
- DSC1 | c.249C>T p.L83= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs765140793, COSV99938008; called by muse, mutect2, varscan2
- EXD3 | c.1227G>A p.G409= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100573849; called by muse, mutect2, varscan2
- FBN1 | c.7218C>T p.C2406= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100355989; called by muse, mutect2, varscan2
- GART | c.132G>A p.K44= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV99279326; called by muse, mutect2, varscan2
- HDGFL2 | c.351C>T p.D117= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs375365209; called by muse, mutect2, varscan2
- INSR | c.2517C>T p.Y839= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs769481102, COSV100252947; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRCH2 | c.6G>A p.A2= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100407284; called by muse, mutect2, varscan2
- OR4K15 | c.696G>C p.L232= (on ENST00000305051; = p.L208= on NM_001005486.1) | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100521115; called by muse, mutect2, varscan2
- PIEZO2 | c.8169G>T p.L2723= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV99555314; called by muse, mutect2, varscan2
- PRPF8 | c.3228C>T p.D1076= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs749422559, COSV100517747; called by muse, mutect2, varscan2
- RUSC1 | c.51C>T p.L17= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99430146; called by muse, mutect2, varscan2
- SLC12A5 | c.2292C>T p.F764= (on ENST00000454036 / NM_001134771.2; = p.F741= on NM_020708.5) | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV54793283; called by muse, mutect2, varscan2
- SMS | c.915G>T p.V305= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV101048222; called by muse, mutect2, varscan2
- SMS | c.916T>C p.L306= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV101048225; called by muse, mutect2, varscan2
- SPAG6 | c.834T>C p.I278= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100510414; called by muse, mutect2, varscan2
- STIM1 | c.324C>T p.F108= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100330918; called by muse, mutect2, varscan2
- SYNGR4 | c.324C>T p.I108= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV61225165; called by muse, mutect2
- TBX2 | c.1425C>T p.H475= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1244936105, COSV99539034; called by muse, mutect2, varscan2
- TECTA | c.6318C>T p.L2106= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV50698519, COSV99880936; called by muse, mutect2, varscan2
- TFRC | c.1926G>A p.L642= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs749863139, COSV100786563; called by muse, mutect2, varscan2
- TNXB | c.11550C>T p.D3850= (on ENST00000647633; = p.D3603= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as rs139430697; called by muse, mutect2, varscan2
- TTC39B | c.207C>T p.L69= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs768572558, COSV99895827; called by muse, varscan2
- TUBGCP3 | c.510C>A p.L170= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99997058; called by muse, mutect2, varscan2
- UGGT2 | c.861G>A p.L287= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs372713290; called by muse, mutect2, varscan2
- WBP11 | c.1533G>A p.L511= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs1344345625, COSV99660806; called by muse, mutect2, varscan2
- ZNF436 | c.1302C>A p.I434= | Silent (SNP) | VAF 42/59 reads (71%) | catalogued as rs1322369086, COSV100011161, COSV100011263; called by muse, mutect2, varscan2
- DKC1 | c.771+225A>C | Intron (SNP) | VAF 26/73 reads (36%) | catalogued as COSV101059894; called by muse, mutect2, varscan2
- HERC2P3 | n.459G>A | RNA (SNP) | VAF 39/293 reads (13%) | catalogued as rs528953010; called by muse, mutect2, varscan2
- MUC2 | chr11:1099334 C>A | 3'Flank (SNP) | VAF 8/45 reads (18%) | catalogued as rs1270008342; called by muse, varscan2
- NPR3 | c.*3265C>T | 3'UTR (SNP) | VAF 11/83 reads (13%) | catalogued as rs753347569, COSV54092875; called by muse, mutect2, varscan2
- SNORA22 | n.98_101del | RNA (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- STMP1 | chr7:135660160 G>T | 5'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
